Somatic mutation profile of tumor specimen TCGA-RW-A7D0-01A (aliquot TCGA-RW-A7D0-01A-11D-A35D-08) from TCGA case TCGA-RW-A7D0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 47.7 years (17,422 days).
Specimen TCGA-RW-A7D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b3c48f2-a627-4b30-8c74-4e36789cae12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A7D0-10A (Blood Derived Normal), aliquot TCGA-RW-A7D0-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de483921-adf1-4388-a44d-620e60e9bdd8

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | catalogued as rs1241533665, CM143318, COSV100647606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLT1 | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV56741279; called by muse, mutect2, varscan2
- GGT1 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV50640099; called by muse, mutect2
- OTUD3 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV99056117; called by muse, mutect2, varscan2
- TCF4 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61899802; called by muse, mutect2
- ZFP2 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.122); catalogued as rs774156214; called by muse, mutect2, varscan2
- CPSF7 | c.1074_1084del p.A359Gfs*4 (on ENST00000394888 / NM_001136040.4; = p.A402Gfs*4 on NM_024811.4) | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- OR10A3 | c.234G>A p.T78= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs755726817; called by muse, mutect2, varscan2
- SPAG4 | c.492C>T p.I164= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV65330891; called by muse, mutect2, varscan2
